Somatic mutation profile of tumor specimen C3L-07972-02 (aliquot CPT0451030006) from CPTAC case C3L-07972, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 63.9 years (23,347 days).
Specimen C3L-07972-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7dab538-2664-4959-836e-01f61c963fcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07972-31 (Blood Derived Normal), aliquot CPT0451170003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78bd220c-0039-4d99-95e6-86ef67f465e3

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Nonsense Mutation 5, 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF18 | c.1834C>T p.R612* (on ENST00000359920 / NM_001130955.2; = p.R508* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/587 reads (7%) | catalogued as rs1064793000; ClinVar: pathogenic; called by muse, mutect2
- CDKN2A | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 50/712 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM014696, COSV58688961, COSV58702489, COSV58705912; called by muse, mutect2
- ARHGEF15 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 35/583 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201103318; called by muse, mutect2
- ATCAY | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs868017605, COSV56660041; called by muse, mutect2
- BIRC6 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.135); catalogued as COSV101428402; called by muse, mutect2
- C1QTNF2 | c.212A>T p.D71V (on ENST00000393975; = p.D26V on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/642 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV67432510; called by muse, mutect2
- C5 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 54/422 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs753562167; called by muse, mutect2, varscan2
- CACNA2D3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs369967606; called by muse, mutect2
- CBLN2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 37/456 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99504129; called by muse, mutect2
- COL9A2 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 45/644 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs1316769098; called by muse, mutect2
- CRX | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778203784, COSV99704529; called by muse, mutect2
- DPYSL4 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV58307499; called by muse, mutect2
- FLRT3 | c.667A>C p.N223H | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs749996521; called by muse, mutect2
- GATA5 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 53/839 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556876322; called by muse, mutect2
- GPRIN2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 38/936 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs781801723, COSV65400461; called by muse, mutect2
- ITGAD | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 36/473 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs200967127, COSV101210427; called by muse, mutect2
- KCNB1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 39/917 reads (4%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.007); catalogued as rs779750227, COSV65566501, COSV65570216; ClinVar: uncertain significance; called by muse, mutect2
- KCNH3 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 42/605 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57790414; called by muse, mutect2
- KIF2B | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 40/608 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV99274508; called by muse, mutect2
- LRRC7 | c.3443C>T p.A1148V (on ENST00000651989 / NM_001370785.2; = p.A1115V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/401 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs149601487; called by muse, mutect2, varscan2
- MAGEL2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 62/899 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1038598112; called by muse, mutect2
- MARK1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 71/510 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763097427, COSV65066687; called by muse, mutect2, varscan2
- MBD3L1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as rs1190292627; called by muse, mutect2
- MUC16 | c.30406C>A p.P10136T | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.01); catalogued as COSV67466681; called by muse, mutect2
- NGFR | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 54/493 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs762741911, COSV50801821; called by muse, mutect2, varscan2
- OR4S2 | c.873A>C p.E291D | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100412572; called by muse, mutect2
- RBM19 | c.1790G>C p.G597A | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.149); catalogued as COSV55693310; called by muse, mutect2
- RGS9BP | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs781181645, COSV60135208; called by muse, mutect2
- SACS | c.12407T>C p.L4136P | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2
- SCO2 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 49/574 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52689692; called by muse, mutect2
- SEMA6D | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV104412987; called by muse, mutect2
- SLC39A14 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs747005078, COSV99249475; called by muse, mutect2
- STAT5A | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs769660748, COSV61807066; called by muse, mutect2
- SUSD2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 56/480 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.968); catalogued as rs145501446; called by muse, mutect2, varscan2
- SYNE1 | c.23996G>T p.R7999L (on ENST00000367255 / NM_182961.4; = p.R7928L on NM_033071.3) | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54919283; called by muse, mutect2
- TENM3 | c.7856G>A p.R2619H | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs1214038143, COSV69299013; called by muse, mutect2
- TPRN | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 172/756 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs373391609; called by muse, varscan2
- XPO1 | c.3144G>C p.E1048D | Missense Mutation (SNP) | VAF 35/513 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV68945776; called by muse, mutect2
- ADGRF1 | c.2309G>A p.W770* | Nonsense Mutation (SNP) | VAF 44/568 reads (8%) | called by muse, mutect2
- ANKRD26 | c.2135T>C p.I712T | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- ATP8A2 | c.3493G>C p.E1165Q | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CEP120 | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.174); called by muse, mutect2
- DNAH11 | c.12544G>A p.A4182T | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.159); called by muse, mutect2
- DNAH7 | c.6700C>A p.Q2234K | Missense Mutation (SNP) | VAF 23/407 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FCHSD2 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- FLG | c.3860C>G p.S1287C | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- GON4L | c.5368A>T p.I1790F | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GRIP1 | c.2848C>T p.R950* (on ENST00000359742 / NM_001379345.1; = p.R898* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 41/584 reads (7%) | called by muse, mutect2
- GTF2IRD2 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 20/628 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); called by muse, mutect2
- MUC17 | c.4565G>A p.S1522N | Missense Mutation (SNP) | VAF 46/544 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- NIT2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2
- OR2Z1 | c.707A>T p.K236M | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PBK | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 31/346 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2
- PCDHGA6 | c.1937T>G p.V646G | Missense Mutation (SNP) | VAF 30/796 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- POFUT1 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 23/507 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2
- RAD51AP1 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2
- SERINC3 | c.617T>A p.L206* | Nonsense Mutation (SNP) | VAF 18/354 reads (5%) | called by muse, mutect2
- SPATA20 | c.1451G>T p.G484V (on ENST00000356488 / NM_001258372.1; = p.G500V on NM_022827.4) | Missense Mutation (SNP) | VAF 87/473 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TLR10 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 13/376 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.753); called by muse, mutect2
- TPH2 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TRIO | c.7207G>A p.E2403K | Missense Mutation (SNP) | VAF 46/567 reads (8%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.359); called by muse, mutect2
- TTC21A | c.2351A>T p.Y784F | Missense Mutation (SNP) | VAF 24/365 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2
- UNC80 | c.4076C>G p.T1359S | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2
- WDR76 | c.932T>G p.V311G | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF550 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADCYAP1 | c.147G>A p.P49= | Silent (SNP) | VAF 36/462 reads (8%) | catalogued as rs1321110930; called by muse, mutect2
- ADGRE3 | c.246C>T p.N82= | Silent (SNP) | VAF 23/359 reads (6%) | catalogued as rs774575203, COSV99506214; called by muse, mutect2
- ARFGEF2 | c.3990C>T p.F1330= | Silent (SNP) | VAF 19/602 reads (3%) | called by muse, mutect2
- CASS4 | c.2064C>T p.S688= | Silent (SNP) | VAF 221/930 reads (24%) | catalogued as rs917007163, COSV64386312; called by muse, mutect2, varscan2
- CDH9 | c.2172C>T p.D724= | Silent (SNP) | VAF 28/420 reads (7%) | catalogued as rs368230951, COSV50261778; called by muse, mutect2
- CDK13 | c.3111T>C p.V1037= | Silent (SNP) | VAF 34/590 reads (6%) | called by muse, mutect2
- ENTPD2 | c.570C>T p.F190= | Silent (SNP) | VAF 61/580 reads (11%) | catalogued as rs993138967; called by muse, mutect2, varscan2
- FLCN | c.582G>A p.R194= | Silent (SNP) | VAF 27/437 reads (6%) | catalogued as rs1044621561; called by muse, mutect2
- GNAS | c.1128G>A p.P376= | Silent (SNP) | VAF 60/923 reads (7%) | catalogued as rs1441723516; called by muse, mutect2
- IL3RA | c.525C>T p.S175= | Silent (SNP) | VAF 54/703 reads (8%) | called by muse, mutect2
- KRTAP20-2 | c.57C>T p.G19= | Silent (SNP) | VAF 39/590 reads (7%) | catalogued as rs1194592664, COSV58182517; called by muse, mutect2
- NCOA1 | c.486G>A p.V162= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as rs754449384; called by muse, mutect2, varscan2
- SCCPDH | c.204G>A p.L68= | Silent (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- SLC12A8 | c.657A>G p.L219= | Silent (SNP) | VAF 32/441 reads (7%) | catalogued as rs1285583407; called by muse, mutect2
- STAU1 | c.663G>A p.S221= (on ENST00000371856 / NM_001319135.1; = p.S140= on NM_004602.3) | Silent (SNP) | VAF 36/663 reads (5%) | catalogued as rs368024753; called by muse, mutect2
- TECTA | c.2901G>A p.A967= | Silent (SNP) | VAF 33/452 reads (7%) | catalogued as rs149546608; called by muse, mutect2
- TNRC18 | c.4644C>T p.S1548= | Silent (SNP) | VAF 28/472 reads (6%) | catalogued as rs754588877; called by muse, mutect2
- USP13 | c.867G>A p.A289= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as rs148480598; called by muse, mutect2
- ZNF189 | c.411C>T p.I137= | Silent (SNP) | VAF 54/445 reads (12%) | called by muse, mutect2, varscan2
- NOTCH1 | c.*841G>A | 3'UTR (SNP) | VAF 26/626 reads (4%) | called by muse, mutect2
- PUF60 | c.*1C>T | 3'UTR (SNP) | VAF 25/391 reads (6%) | called by muse, mutect2
- ZNF662 | c.-94+192C>T | Intron (SNP) | VAF 53/379 reads (14%) | catalogued as rs1379192465; called by muse, mutect2, varscan2
